Somatic mutation profile of tumor specimen ALCH-B373-TTP1-A (aliquot ALCH-B373-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B373, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.5 years (23,547 days).
Specimen ALCH-B373-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37436c77-03ca-48a9-9b21-54cebfe736c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B373-NB1-A (Blood Derived Normal), aliquot ALCH-B373-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c48aab0-f00e-4696-a738-1f7b43dd6187

The open-access MAF lists 297 somatic variants for this specimen: 193 protein-altering or splice-affecting, 65 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 65, Intron 21, Nonsense Mutation 14, Splice Site 10, RNA 6, Frame Shift Del 5, 3'UTR 4, 5'Flank 3, 5'UTR 3, Frame Shift Ins 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 69/241 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.2925G>C p.E975D | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV99059526; called by muse, mutect2
- APPL2 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.189); catalogued as COSV51588026; called by muse, mutect2, varscan2
- ARHGAP23 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as rs572206818; called by muse, mutect2
- ARHGAP28 | c.1840G>A p.E614K (on ENST00000383472 / NM_001366230.1; = p.E455K on NM_001010000.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs747306958; called by mutect2, varscan2
- ASPH | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.897); catalogued as rs78393038; called by muse, mutect2
- BRCA1 | c.5197G>C p.D1733H | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs398122693, COSV58788914; ClinVar: not provided / uncertain significance; called by muse, mutect2
- C1orf112 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as rs776564618; called by muse, mutect2, varscan2
- C2CD6 | c.1559T>C p.I520T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs1345225361; called by muse, mutect2, varscan2
- C3 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as COSV55575535; called by muse, mutect2
- CDH23 | c.6643G>A p.V2215M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs746755852; called by muse, mutect2, varscan2
- CEMIP | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 25/327 reads (8%) | catalogued as rs747919572; called by muse, mutect2
- CFAP47 | c.2675C>G p.T892R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); catalogued as rs1286666706; called by muse, mutect2, varscan2
- CYP1A2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV59659440; called by muse, mutect2, varscan2
- DLG5 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1046674552, COSV64947139; called by muse, mutect2
- DZIP3 | c.1589G>T p.W530L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs781443126; called by muse, varscan2
- EGF | c.2327A>T p.D776V | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs767731807; called by muse, mutect2, varscan2
- FBN2 | c.532+1G>T p.X178_splice | Splice Site (SNP) | VAF 35/149 reads (23%) | catalogued as COSV52513803; called by muse, mutect2, varscan2
- FBXO39 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as rs766401032; called by muse, mutect2, varscan2
- FLNC | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV100367800; called by muse, mutect2
- FSHR | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as rs369191560, COSV58624116; called by muse, mutect2, varscan2
- GLYAT | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53540878; called by muse, mutect2, varscan2
- GPR149 | c.1174dup p.I392Nfs*7 | Frame Shift Ins (INS) | VAF 16/72 reads (22%) | catalogued as rs1415549771; called by mutect2, varscan2
- HCN1 | c.1752G>C p.E584D | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV100298478; called by muse, varscan2
- HERC1 | c.13390A>G p.M4464V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1311477920; called by muse, mutect2, varscan2
- HSPA9 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as rs150186605; called by muse, mutect2, varscan2
- IFIH1 | c.2498T>A p.V833D | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268126052; called by muse, mutect2
- IQCE | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58076517; called by muse, mutect2, varscan2
- ITPR2 | c.2896G>A p.V966M | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs552466047, COSV67273412; called by muse, mutect2, varscan2
- ITSN1 | c.561A>T p.R187S | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.916); catalogued as rs1227209877, COSV101180643; called by muse, mutect2, varscan2
- KEAP1 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV50260883; called by muse, mutect2, varscan2
- KLHL34 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs977919866; called by muse, mutect2, varscan2
- LAMA3 | c.5048G>T p.R1683L (on ENST00000313654 / NM_198129.4; = p.R74L on NM_000227.6) | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV52534623; called by muse, mutect2, varscan2
- LDLRAD4 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV63344190; called by muse, mutect2, varscan2
- MGAT4C | c.1199A>G p.D400G | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1232995200; called by muse, mutect2, varscan2
- MLH1 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV51618816; called by muse, mutect2, varscan2
- MRPS21 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100481670; called by muse, mutect2, varscan2
- MS4A18 | c.896A>G p.N299S (on ENST00000398983; = p.N301S on NM_001354471.1) | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1274841591; called by muse, mutect2, varscan2
- MTF2 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 19/181 reads (10%) | catalogued as COSV64769577; called by muse, mutect2, varscan2
- MYH1 | c.4531C>G p.Q1511E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56853315; called by muse, mutect2, varscan2
- NEXMIF | c.4151G>T p.G1384V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV50025078; called by muse, mutect2, varscan2
- NPAP1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs199720232; called by muse, mutect2, varscan2
- NTRK2 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs780831721, COSV52869189; called by muse, mutect2, varscan2
- OPRM1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 6/117 reads (5%) | catalogued as rs867865977, COSV57676277; called by muse, mutect2
- PRDM5 | c.1694G>A p.R565K | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV53362136; called by muse, mutect2
- RAB4B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV104373387; called by muse, mutect2, varscan2
- RBCK1 | c.440G>A p.R147Q (on ENST00000356286 / NM_031229.4; = p.R105Q on NM_006462.6) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756500607; called by muse, mutect2, varscan2
- RIC8B | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62694660; called by muse, mutect2
- RP1 | c.5551C>T p.H1851Y | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.014); catalogued as COSV55122480; called by muse, mutect2
- RPS24 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV71268066; called by muse, mutect2, varscan2
- SALL3 | c.2421C>A p.D807E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV73305993; called by muse, mutect2
- SH3BGRL2 | c.313-1G>T p.X105_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | catalogued as rs776520612; called by muse, mutect2
- SLC8A1 | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60500359; called by muse, mutect2
- SNX13 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as rs1333408532; called by muse, mutect2, varscan2
- SPECC1 | c.2151G>C p.E717D | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV54953497; called by muse, mutect2
- STOX1 | c.1329G>T p.Q443H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100058337; called by muse, mutect2, varscan2
- TAF5L | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV99273509; called by muse, mutect2
- TANC1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1260315858, COSV55088297; called by muse, mutect2, varscan2
- TCF23 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV56078525; called by muse, mutect2, varscan2
- TMED8 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs777855396, COSV104370286; called by muse, mutect2, varscan2
- TMPRSS11B | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as rs1485072440; called by muse, mutect2
- VPS50 | c.2208G>T p.L736F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100004694, COSV59921889; called by muse, mutect2, varscan2
- XIRP2 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753561084; called by muse, mutect2
- ZNF197 | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV60360237; called by muse, mutect2, varscan2
- ZNF804B | c.2185C>A p.H729N | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.518); catalogued as COSV60832697; called by muse, mutect2, varscan2
- ABCA13 | c.9853G>T p.D3285Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- ABL1 | c.2718_2746del p.A907Efs*23 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel
- ACCSL | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ACTR3B | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS12 | c.4255T>A p.C1419S | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRV1 | c.5310C>G p.Y1770* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2
- AICDA | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 50/361 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMBRA1 | c.2051C>G p.S684C (on ENST00000458649 / NM_001367468.1; = p.S594C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ANKRD30A | c.1817G>A p.G606D (on ENST00000611781; = p.G550D on NM_052997.2) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANP32B | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASCL1 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- BDKRB1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BPIFB1 | c.927+2T>A p.X309_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- BPTF | c.5758G>T p.D1920Y | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRINP3 | c.2269A>G p.M757V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- BTG4 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); called by muse, mutect2
- CAPN14 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CCDC144A | c.3954A>T p.R1318S | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- CCDC168 | c.8512T>C p.F2838L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CD163L1 | c.3104G>T p.R1035L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPG | c.3454G>T p.G1152C | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDC7 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFDP1 | c.531G>T p.R177S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CFDP1 | c.531-1G>T p.X177_splice | Splice Site (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- CHD1 | c.4060G>C p.D1354H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- COL19A1 | c.2623-1G>A p.X875_splice | Splice Site (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- COL22A1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- CPSF3 | c.1766C>A p.S589* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- DCDC2C | c.1022A>G p.K341R | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, varscan2
- DDX39B | c.413_428del p.K138Tfs*19 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- DGCR8 | c.1788+1G>A p.X596_splice | Splice Site (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- DIP2C | c.3685_3691del p.T1229Afs*5 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- DNAH11 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DOCK2 | c.3726C>A p.Y1242* | Nonsense Mutation (SNP) | VAF 66/254 reads (26%) | called by muse, mutect2, varscan2
- DOCK5 | c.4842G>C p.Q1614H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- DUOX1 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC1I1 | c.1792T>A p.S598T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.277); called by muse, mutect2
- ENTPD6 | c.574A>C p.K192Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EVC2 | c.1956C>G p.I652M | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- EXO1 | c.895A>T p.N299Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCRL5 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- FEZF2 | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.074); called by mutect2, varscan2
- FGFR4 | c.2093T>A p.L698Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FZD10 | c.1745G>T p.*582Lext*46 | Nonstop Mutation (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- GCKR | c.968+1G>T p.X323_splice | Splice Site (SNP) | VAF 62/370 reads (17%) | called by muse, mutect2, varscan2
- GK | c.755G>T p.G252V (on ENST00000427190 / NM_001205019.2; = p.G246V on NM_000167.6) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GLI3 | c.2456G>T p.S819I | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- H4C11 | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, varscan2
- HCN1 | c.1684T>C p.Y562H | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, varscan2
- HEYL | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- HMCN1 | c.3337T>G p.W1113G | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMGB3 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- HS6ST3 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTR1A | c.988_1008del p.E330_A336del | In Frame Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- IGKV1-5 | c.55+1G>T p.X19_splice | Splice Site (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- IGSF9B | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.479); called by muse, mutect2
- INTU | c.1458A>T p.L486F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2
- KCNJ3 | c.547A>T p.K183* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- KDM6A | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- KLHL31 | c.516C>G p.C172W | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- KMT2D | c.3595C>G p.L1199V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LGSN | c.90G>T p.R30S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LHX3 | c.364A>G p.K122E (on ENST00000371748 / NM_178138.6; = p.K127E on NM_014564.5) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- LLGL2 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.042); called by muse, mutect2
- LTN1 | c.4146G>T p.L1382F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MAST1 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTDH | c.1516A>T p.S506C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- NAV3 | c.1799C>A p.T600K | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NBAS | c.2164A>T p.N722Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- NCKAP1L | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NID1 | c.2642_2657del p.H881Pfs*30 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by pindel, varscan2
- NLRP12 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- NUP43 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ONECUT2 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- OR10A3 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR14A2 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- OR2T11 | c.597C>G p.C199W | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2W1 | c.658T>A p.Y220N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- OR6Q1 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PCNX2 | c.886A>G p.R296G | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PDCD11 | c.1632G>T p.Q544H | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- PHACTR3 | c.152A>T p.E51V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- PHF11 | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PIFO | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- PLCG2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PLEKHH3 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, varscan2
- PRDM16 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRUNE2 | c.3400A>G p.N1134D | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PXDNL | c.2003C>G p.T668R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RABGAP1 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2
- RAPGEF6 | c.2031G>T p.R677S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM43 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- RD3 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.157); called by muse, varscan2
- RGSL1 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- RIMS1 | c.1671C>G p.S557R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SBF1 | c.1238A>T p.D413V | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SCFD1 | c.1136C>G p.T379S | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- SCN10A | c.5086G>C p.A1696P | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SCYL2 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- SEL1L3 | c.3346G>T p.A1116S | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.005); called by muse, mutect2
- SH3BP5L | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SIK3 | c.3324G>T p.R1108S (on ENST00000445177 / NM_001366686.2; = p.R1066S on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- SIK3 | c.3323G>A p.R1108K (on ENST00000445177 / NM_001366686.2; = p.R1066K on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2
- SLC17A6 | c.1239C>G p.I413M | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SLC30A2 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC38A9 | c.816del p.Y272* | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | called by mutect2, pindel, varscan2
- SLC39A4 | c.869dup p.E291Gfs*127 (on ENST00000301305 / NM_001374839.1; = p.E266Gfs*127 on NM_017767.3) | Frame Shift Ins (INS) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.1765G>C p.V589L | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SPAST | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SPATA19 | c.259A>T p.R87* | Nonsense Mutation (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- SPOCK1 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- TBX18 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TENM3 | c.5182A>C p.N1728H | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- TEX45 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2
- TGFBR3L | c.818T>A p.V273E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- TPTE2 | c.300C>A p.S100R (on ENST00000400230 / NM_199254.2; = p.S63R on NM_130785.3) | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAV6 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- TSPO2 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by mutect2, varscan2
- TSPOAP1 | c.5111A>C p.Q1704P | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- UBASH3A | c.1738+1G>T p.X580_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- USP54 | c.2959C>A p.H987N | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2
- VPS50 | c.2208-1G>A p.X736_splice | Splice Site (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- ZBTB32 | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZCWPW1 | c.1459A>G p.T487A | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ZDBF2 | c.6258C>A p.S2086R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP37 | c.1770A>G p.I590M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- ZNF713 | c.835G>T p.G279* (on ENST00000633730 / NM_001366796.2; = p.G292* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- ABCC9 | c.2520A>T p.S840= | Silent (SNP) | VAF 49/207 reads (24%) | called by muse, mutect2, varscan2
- ACIN1 | c.1269A>G p.A423= | Silent (SNP) | VAF 65/370 reads (18%) | catalogued as rs753030066; called by muse, mutect2, varscan2
- ACKR1 | c.591G>T p.L197= | Silent (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
- ACOXL | c.114C>A p.V38= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.1629G>T p.V543= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- ALPP | c.783G>A p.A261= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs749165151; called by muse, mutect2, varscan2
- ANKFY1 | c.936G>C p.G312= | Silent (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- C1orf105 | c.261A>G p.Q87= | Silent (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- C4orf54 | c.2928C>T p.L976= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs1256058685; called by muse, mutect2, varscan2
- CACNG6 | c.444C>A p.G148= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs1342551575; called by muse, mutect2, varscan2
- CAPN13 | c.1176C>G p.V392= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- CHD5 | c.483C>T p.Y161= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs752864729; called by muse, mutect2, varscan2
- CLDN18 | c.117C>A p.P39= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV99480529, COSV99481067; called by muse, mutect2, varscan2
- CLIC2 | c.282G>T p.L94= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- CLUH | c.3102C>A p.G1034= (on ENST00000435359; = p.G1073= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101425812; called by muse, mutect2
- COL20A1 | c.1377G>T p.R459= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- DBH | c.402G>A p.L134= | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- DDX3X | c.1985G>A p.*662= (on ENST00000399959; = p.*663= on NM_001356.5) | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- DTNA | c.1425G>A p.L475= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as COSV99315497; called by muse, mutect2
- ELOVL6 | c.213A>T p.A71= | Silent (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- EN2 | c.807G>C p.L269= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- EYS | c.909T>C p.F303= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- FAM149A | c.2100G>A p.S700= (on ENST00000356371 / NM_001367768.2; = p.S409= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs373524360; called by muse, mutect2, varscan2
- HCN1 | c.2604A>C p.P868= | Silent (SNP) | VAF 54/395 reads (14%) | called by muse, varscan2
- HDAC7 | c.1797G>A p.L599= (on ENST00000427332; = p.L638= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- IFNA17 | c.411G>A p.E137= | Silent (SNP) | VAF 15/246 reads (6%) | catalogued as rs770354330; called by muse, mutect2
- IGKV1-8 | c.111C>T p.D37= | Silent (SNP) | VAF 51/240 reads (21%) | called by muse, mutect2, varscan2
- KIF21B | c.2395C>A p.R799= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- KIF26B | c.3072C>T p.S1024= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs917373092; called by muse, mutect2
- KMT2C | c.12432C>T p.L4144= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as rs924388772, COSV51490445; called by muse, mutect2
- LRRC18 | c.262C>T p.L88= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1447522533; called by muse, mutect2, varscan2
- LZTS3 | c.1713G>T p.R571= (on ENST00000329152; = p.R525= on NM_001282533.2) | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- MAGEB10 | c.504G>A p.L168= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV63312793; called by muse, mutect2, varscan2
- MYO18B | c.7305C>A p.R2435= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- NUMBL | c.1062C>T p.A354= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs140986186; called by muse, mutect2, varscan2
- NYAP1 | c.747C>T p.G249= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1264510338, COSV55719317; called by muse, mutect2, varscan2
- OR1L1 | c.876C>A p.G292= (on ENST00000373686; = p.G242= on NM_001005236.3) | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- OR2G2 | c.855C>A p.T285= | Silent (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- OR2T27 | c.942A>T p.V314= | Silent (SNP) | VAF 58/294 reads (20%) | called by muse, varscan2
- OR4K5 | c.786T>C p.F262= | Silent (SNP) | VAF 45/369 reads (12%) | called by muse, mutect2, varscan2
- OR5M1 | c.321G>C p.L107= | Silent (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- OR9K2 | c.207G>A p.G69= (on ENST00000305377; = p.G47= on NM_001005243.1) | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as rs767268577; called by muse, mutect2
- PCLO | c.11706A>G p.S3902= | Silent (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.120G>A p.E40= | Silent (SNP) | VAF 70/216 reads (32%) | called by muse, mutect2, varscan2
- PDPR | c.1650C>T p.S550= | Silent (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2, varscan2
- PFKFB3 | c.1401C>T p.S467= | Silent (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- PIK3CG | c.483C>T p.D161= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1297603558, COSV63252154; called by muse, mutect2, varscan2
- PLCH1 | c.4593G>T p.V1531= (on ENST00000340059 / NM_001130960.2; = p.V1523= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/168 reads (21%) | called by muse, mutect2, varscan2
- PPP2R3A | c.1464A>G p.K488= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- PREX1 | c.3480C>A p.G1160= | Silent (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- PRR23C | c.423C>G p.V141= | Silent (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- RICTOR | c.1677T>C p.N559= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- SCAF1 | c.2388G>T p.R796= | Silent (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- SCUBE2 | c.711C>T p.C237= | Silent (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- SHD | c.732C>A p.P244= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs1357920379; called by muse, mutect2, varscan2
- SIGLEC1 | c.831C>G p.L277= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, varscan2
- SLAMF7 | c.18A>G p.T6= | Silent (SNP) | VAF 31/171 reads (18%) | called by muse, mutect2, varscan2
- SOD2 | c.102C>T p.D34= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- TEC | c.1272G>A p.K424= | Silent (SNP) | VAF 6/129 reads (5%) | catalogued as rs1419886084; called by muse, mutect2
- TTC23L | c.981C>A p.I327= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, varscan2
- TTN | c.55620T>A p.I18540= (on ENST00000591111; = p.I11116= on NM_003319.4) | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- UTP4 | c.1236G>T p.R412= | Silent (SNP) | VAF 30/330 reads (9%) | catalogued as rs754208879, COSV100076997; called by muse, mutect2
- ZBBX | c.1983A>C p.A661= | Silent (SNP) | VAF 27/218 reads (12%) | called by muse, mutect2, varscan2
- ZNF507 | c.957G>A p.G319= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs955916027; called by muse, mutect2
- ZNF69 | c.1257G>A p.K419= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- AC074085.2 | n.289G>T | RNA (SNP) | VAF 28/186 reads (15%) | catalogued as rs376320948; called by muse, mutect2, varscan2
- ACTR3BP2 | n.995C>A | RNA (SNP) | VAF 8/88 reads (9%) | catalogued as rs1377251952; called by muse, mutect2
- ARHGEF2 | chr1:155983189 A>T | 5'Flank (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2
- ATCAY | c.78-7311A>T | Intron (SNP) | VAF 18/347 reads (5%) | called by muse, mutect2
- ATP1A3 | c.6+49C>A | Intron (SNP) | VAF 10/49 reads (20%) | catalogued as rs936654296; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*190C>T | 3'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as rs924318420; called by muse, mutect2, varscan2
- CACNA1B | c.530+9413G>A | Intron (SNP) | VAF 18/176 reads (10%) | catalogued as rs981407376; called by muse, mutect2
- CDH15 | c.663+122G>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- DCHS2 | n.316C>T | RNA (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2
- DDX23 | c.1383-630G>T | Intron (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- DPP10 | c.61-244460G>A | Intron (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- EVX1 | chr7:27239313 G>T | 5'Flank (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- FASN | c.6827-48C>T | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- FGFR2 | c.-68G>T | 5'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- FGG | c.401+16T>G | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- GDF3 | c.*24G>T | 3'UTR (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- GP2 | c.94+31T>C | Intron (SNP) | VAF 21/73 reads (29%) | catalogued as rs1182816678; called by muse, mutect2, varscan2
- GP6 | c.35-50A>C | Intron (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- HUS1 | c.465+397A>G | Intron (SNP) | VAF 27/115 reads (23%) | catalogued as rs1284605118; called by muse, mutect2, varscan2
- JPH3 | chr16:87702080 C>A | 3'Flank (SNP) | VAF 17/124 reads (14%) | catalogued as rs955914888; called by muse, mutect2, varscan2
- KEL | c.3+77G>T | Intron (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- KLF6 | c.*3217G>A | 3'UTR (SNP) | VAF 8/152 reads (5%) | catalogued as rs1256817217; called by muse, mutect2
- LGI1 | c.288-30C>G | Intron (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- LINC01164 | n.942del | RNA (DEL) | VAF 36/168 reads (21%) | called by mutect2, pindel, varscan2
- LINGO3 | c.-76T>C | 5'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- MARCHF1 | c.242+932G>T | Intron (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2
- MED23 | c.*853G>A | 3'UTR (SNP) | VAF 24/104 reads (23%) | catalogued as rs898388962; called by muse, mutect2, varscan2
- OR4C4P | n.647C>G | RNA (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- OR51F5P | n.341C>A | RNA (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- PACRG | c.613+89812G>T | Intron (SNP) | VAF 37/185 reads (20%) | catalogued as rs971353247; called by muse, mutect2, varscan2
- PAX6 | c.142-16C>T | Intron (SNP) | VAF 9/177 reads (5%) | catalogued as rs1156909619; called by muse, mutect2
- PEX11B | chr1:145919705 A>G | 5'Flank (SNP) | VAF 37/119 reads (31%) | catalogued as rs1181592326; called by muse, mutect2, varscan2
- PRSS40A | n.142-2287T>A | Intron (SNP) | VAF 26/217 reads (12%) | catalogued as COSV101301951; called by muse, mutect2, varscan2
- RAPGEF1 | c.1855-2858C>T | Intron (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- RN7SL319P | chr15:75786415 G>A | 3'Flank (SNP) | VAF 49/207 reads (24%) | catalogued as rs748682349; called by muse, mutect2, varscan2
- ROBO2 | c.1971+20G>T | Intron (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- RPL10 | c.23+44G>T | Intron (SNP) | VAF 19/39 reads (49%) | catalogued as rs782722235; called by muse, mutect2, varscan2
- STK16 | c.657+62G>T | Intron (SNP) | VAF 50/208 reads (24%) | called by muse, mutect2, varscan2
- ZNF879 | c.-16C>T | 5'UTR (SNP) | VAF 53/174 reads (30%) | catalogued as COSV101469771; called by muse, mutect2, varscan2
